Somatic mutation profile of tumor specimen 0DIY6C from CCDI case PBBWIJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,364 days).
Specimen 0DIY6C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f9214d5-bd72-41d1-aa2a-5de55005ed9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY61 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6f1e95f-c0fb-4f08-9e2b-b9ad4b6f3d38

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF26B | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 190/1265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTPRM | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 127/1220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RPL36A | c.110-4C>T | Splice Region (SNP) | VAF 78/988 reads (8%) | called by muse, mutect2
- TRAF3IP1 | c.1950C>G p.L650= | Silent (SNP) | VAF 347/866 reads (40%) | called by muse, mutect2, varscan2
- TUBE1 | c.48C>T p.I16= | Silent (SNP) | VAF 56/1678 reads (3%) | called by muse, mutect2
- BRCA1 | c.4096+99_4096+101del | Intron (DEL) | VAF 28/160 reads (18%) | called by mutect2, varscan2
- CYB5D1 | c.160+44C>A | Intron (SNP) | VAF 40/678 reads (6%) | called by muse, mutect2
- TMEM266 | c.769-62C>T | Intron (SNP) | VAF 47/324 reads (15%) | called by muse, mutect2, varscan2
